Somatic mutation profile of tumor specimen 0DRB5Q from CCDI case PBCFJK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Conjunctiva; Age at diagnosis: 3.6 years (1,323 days).
Specimen 0DRB5Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5c45be8-44e3-4e69-a108-37b76b7e20cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRB5T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d085acbe-4fd7-4d82-a706-b4021d6bb096

The open-access MAF lists 51 somatic variants for this specimen: 28 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 14, Intron 5, 5'UTR 3, Nonsense Mutation 3, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 245/809 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146979323; called by muse, mutect2, varscan2
- BCORL1 | c.2686G>C p.V896L | Missense Mutation (SNP) | VAF 145/449 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.109); catalogued as COSV99500893; called by muse, mutect2, varscan2
- COL19A1 | c.1980T>A p.N660K | Missense Mutation (SNP) | VAF 36/772 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs982444961; called by muse, mutect2
- DLC1 | c.2393G>A p.R798H (on ENST00000276297 / NM_001348081.2; = p.R361H on NM_006094.5) | Missense Mutation (SNP) | VAF 486/1582 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs755906883, COSV52305962; called by muse, mutect2, varscan2
- EIF2AK3 | c.1650G>C p.R550S | Missense Mutation (SNP) | VAF 163/643 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1254187256; called by muse, mutect2, varscan2
- EPHA5 | c.1066A>G p.R356G | Missense Mutation (SNP) | VAF 161/525 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as rs757242674; called by muse, mutect2, varscan2
- FAM214A | c.2673C>G p.F891L | Missense Mutation (SNP) | VAF 126/439 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55922978; called by muse, mutect2, varscan2
- GPR83 | c.982T>A p.F328I | Missense Mutation (SNP) | VAF 189/1357 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99703724; called by muse, mutect2, varscan2
- LRRFIP2 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 157/504 reads (31%) | catalogued as COSV60868703; called by muse, mutect2, varscan2
- MIB2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 278/821 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294966120; called by muse, mutect2, varscan2
- TINAGL1 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 241/836 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs148269987; called by muse, mutect2, varscan2
- TRIP12 | c.4029G>C p.R1343S | Missense Mutation (SNP) | VAF 38/980 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV99390777; called by muse, mutect2
- VWDE | c.541+1G>C p.X181_splice | Splice Site (SNP) | VAF 110/521 reads (21%) | catalogued as COSV51725571; called by muse, mutect2, varscan2
- AC053503.6 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 78/513 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ALPK1 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 184/832 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC198 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 103/361 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CER1 | c.702G>T p.M234I | Missense Mutation (SNP) | VAF 112/1614 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2
- CFAP47 | c.2871G>T p.L957F | Missense Mutation (SNP) | VAF 230/787 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- DOCK2 | c.1582G>T p.A528S | Missense Mutation (SNP) | VAF 32/995 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2
- DPPA5 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 68/864 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- FBXO46 | c.1644C>A p.H548Q | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H3C6 | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 349/1163 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KCNH5 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 167/831 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT86 | c.1093C>A p.R365S | Missense Mutation (SNP) | VAF 341/1836 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by mutect2, varscan2
- NHEJ1 | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 82/1801 reads (5%) | called by muse, mutect2
- OR5W2 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 247/1294 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- TBCEL | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 92/625 reads (15%) | called by muse, mutect2, varscan2
- VAV3 | c.1584A>C p.K528N | Missense Mutation (SNP) | VAF 144/841 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ALPG | c.528C>T p.A176= | Silent (SNP) | VAF 248/1057 reads (23%) | catalogued as rs761377449, COSV54967869; called by muse, mutect2, varscan2
- CLEC18A | c.228C>T p.D76= | Silent (SNP) | VAF 274/480 reads (57%) | called by muse, mutect2, varscan2
- ERI2 | c.762G>T p.L254= | Silent (SNP) | VAF 156/546 reads (29%) | called by muse, varscan2
- FBXO36 | c.291C>G p.L97= | Silent (SNP) | VAF 182/976 reads (19%) | catalogued as rs757917554; called by muse, mutect2
- HELZ2 | c.4767C>A p.G1589= (on ENST00000467148 / NM_001037335.2; = p.G1020= on NM_033405.3) | Silent (SNP) | VAF 108/494 reads (22%) | called by muse, mutect2, varscan2
- LAMC3 | c.4482G>A p.S1494= | Silent (SNP) | VAF 127/516 reads (25%) | catalogued as rs541113508, COSV62654997; called by muse, mutect2, varscan2
- MLXIP | c.582C>T p.D194= | Silent (SNP) | VAF 186/959 reads (19%) | catalogued as rs369544906; called by muse, mutect2, varscan2
- NYNRIN | c.4608C>G p.V1536= | Silent (SNP) | VAF 122/542 reads (23%) | catalogued as COSV101230582; called by muse, mutect2, varscan2
- OR10G2 | c.354C>T p.F118= | Silent (SNP) | VAF 36/904 reads (4%) | catalogued as COSV73390372; called by muse, mutect2
- PRKCQ | c.408G>A p.T136= | Silent (SNP) | VAF 135/707 reads (19%) | catalogued as rs768802206, COSV99576068, COSV99577721; called by muse, mutect2, varscan2
- TEX55 | c.939A>G p.Q313= | Silent (SNP) | VAF 117/710 reads (16%) | catalogued as rs112908743; called by muse, mutect2, varscan2
- TFAP2E | c.951G>T p.T317= | Silent (SNP) | VAF 136/409 reads (33%) | called by muse, mutect2, varscan2
- TMEM132C | c.2382C>T p.N794= | Silent (SNP) | VAF 259/1269 reads (20%) | catalogued as rs769075838, COSV100176309; called by muse, mutect2, varscan2
- USP43 | c.2514C>A p.S838= | Silent (SNP) | VAF 101/441 reads (23%) | called by muse, mutect2, varscan2
- AGAP3 | c.1020+553G>A | Intron (SNP) | VAF 144/587 reads (25%) | catalogued as rs1238454818; called by muse, mutect2, varscan2
- ANKRA2 | c.-58C>A | 5'UTR (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- CFB | c.1624+95C>A | Intron (SNP) | VAF 60/175 reads (34%) | catalogued as COSV100191709; called by muse, mutect2, varscan2
- NLRP3 | c.-37C>T | 5'UTR (SNP) | VAF 159/527 reads (30%) | catalogued as rs751606929, COSV100276415, COSV60228410; called by muse, mutect2, varscan2
- NRG1 | c.502+31152A>G | Intron (SNP) | VAF 232/1407 reads (16%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/241 reads (11%) | called by muse, varscan2
- SLAIN1 | c.850+53G>T | Intron (SNP) | VAF 136/454 reads (30%) | called by muse, mutect2, varscan2
- SRPK2 | chr7:105389378 G>A | 5'Flank (SNP) | VAF 211/916 reads (23%) | catalogued as rs1563325490; called by muse, mutect2, varscan2
- UBXN6 | c.1052-23G>A | Intron (SNP) | VAF 193/760 reads (25%) | catalogued as rs372305065; called by muse, mutect2, varscan2
